Somatic mutation profile of tumor specimen 0DLHOY from CCDI case PBBYYY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,089 days).
Specimen 0DLHOY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78473c77-5463-47bd-8101-2143ee1c0cb2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLHOH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8d19c53-234b-44a6-862f-1dad3a8fa438

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, 3'UTR 1, Nonsense Mutation 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL031777.2 | c.484A>T p.R162* | Nonsense Mutation (SNP) | VAF 337/780 reads (43%) | catalogued as COSV61912585; called by muse, mutect2, varscan2
- FAM76B | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 357/887 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs372898056; called by muse, mutect2, varscan2
- GRM5 | c.3248C>T p.A1083V (on ENST00000305447 / NM_001143831.2; = p.A1051V on NM_000842.4) | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); catalogued as rs1362348532; called by muse, mutect2
- MOB3B | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 221/474 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.9); catalogued as rs781031539, COSV51779107; called by muse, mutect2, varscan2
- EZH2 | c.1939T>C p.S647P (on ENST00000460911 / NM_001203247.2; = p.S652P on NM_004456.5) | Missense Mutation (SNP) | VAF 368/858 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPLKIP | c.522dup p.G175Rfs*26 | Frame Shift Ins (INS) | VAF 276/643 reads (43%) | called by mutect2, varscan2
- NEDD4 | c.1742C>A p.A581E (on ENST00000508342 / NM_001284338.1; = p.A162E on NM_006154.4) | Missense Mutation (SNP) | VAF 219/651 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRRC2A | c.1509G>T p.R503= | Silent (SNP) | VAF 154/458 reads (34%) | catalogued as COSV63224552; called by muse, mutect2, varscan2
- HFM1 | c.1395+82A>T | Intron (SNP) | VAF 93/207 reads (45%) | catalogued as rs1327819894, COSV54034282; called by muse, mutect2, varscan2
- SKIL | c.*97C>T | 3'UTR (SNP) | VAF 45/94 reads (48%) | catalogued as rs1451343934; called by muse, mutect2, varscan2
